HCMI case HCM-BROD-0010-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5d47d75b-1c71-4864-a2d9-b7f55967c6f4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1962; Vital status: Dead; Days to death: 292 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.7; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 53.9 years (19,673 days); Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Sites of involvement: Liver.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 18 days; Days to treatment end: 182 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Nab-paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 216 days; Days to treatment end: 286 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 15 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 15 days.
- Days to follow up: 286 days; Disease response: Stable Disease; Progression or recurrence: No.

Molecular and laboratory tests
- CA19-9: 9363.
- CEA: 3; Blood test normal range upper: 2.5.
- KRAS substitution: Positive; Amino-acid change: p.Gly12Asp.
- SMAD4 (IHC): Positive.
- TP53 substitution: Positive; Amino-acid change: V216M.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 77.4 kg; Height: 161.4 cm; BMI: 29.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples)
- Sample HCM-BROD-0010-C25-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: Frozen.
- Sample HCM-BROD-0010-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample HCM-BROD-0010-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
